Surgical pathology report (de-identified scan), TCGA case TCGA-64-5779, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-5779-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Clinical History/Diagnosis: Left lung CA

Source of Specimen(s):

- 1: Portion 6th rib
- 2: Level 9 lymph node
- 3: Level 5 lymph node
- 4: Diaphragmatic adhesion
- 5: 11L lymph node
- 6: 12L lymph node
- 7: Level 8 lymph node
- 8: Level 7 lymph node
- 9: Left lung
- 10: New bronchial margin
- 11: Level 6 lymph node

[REDACTED]

TCGA-64-5779

Final Diagnosis:

1. Portion of 6th rib, excision:
No tumor seen.

2. Level 9 lymph nodes, excision:
Seven lymph nodes, no tumor seen (0/7).

3. Level 5 lymph nodes, excision:
Metastatic carcinoma in two of fifteen lymph nodes (2/15).

4. Diaphragmatic adhesion, excision:
Fibrous adhesion.

5. 11L lymph nodes, excision:
Metastatic carcinoma in three of six lymph nodes (3/6)

6. 12L lymph nodes, excision:
Five lymph nodes, no tumor seen (0/5).

7. Level 8 lymph nodes, excision:
Two lymph nodes, no tumor seen (0/2).

8. Level 7 lymph nodes, excision:
Two lymph nodes, no tumor seen (0-/2).

8. Level 7 lymph nodes, excision:
Metastatic carcinoma in two of three lymph nodes (2/3).

9. Left lung, pneumonectomy:
Adenocarcinoma, WHO acinar subtype.
- The 8.5 cm poorly differentiated carcinoma does not invade visceral pleura.
- Angiolymphatic invasion is identified.
- Surgical resection margins are free of carcinoma.

[page 2 of 4]
Emphysema.

Metastatic carcinoma in four of twelve peribronchial lymph nodes (4/12).

10. New bronchial margin, excision:

No tumor seen.

11. Level 6 lymph node, excision:

Three lymph nodes, no tumor seen (0/3).

TCGA-64-5779

Gross Description:

Received in eleven parts.

Source of Tissue: 1. Labeled #1, "portion of rib"

Gross Description: Received fresh labeled, ,
portion of rib". It consists of a portion of rib measuring 5 x 1.3 x 0.7
cm. Representative sections are submitted in 1A following decalcification.

Source of Tissue: 2. Labeled #2, "level 9 lymph node"

Gross Description: Received fresh labeled, ,
level 9 lymph node". It consists of a soft brown lymph node measuring 1.8
x 1 x 0.5 cm. The lymph node is bisected and entirely submitted in 2A.

Source of Tissue: 3. Labeled #3, "level 9 lymph node"

Gross Description: Received fresh labeled, ,
level 9 lymph node". It consists of multiple soft yellow tan lymph nodes
measuring from 0.5 up to 0.9 cm in greatest dimension. The lymph nodes are
entirely submitted in 3A-3B.

Designation of Sections: 3A- two bisected lymph nodes, 3B- multiple
additional lymph nodes

Source of Tissue: 4. Labeled #4, "diaphragmatic adhesion"

Intraoperative Consultation: INFLAMMATORY AND MESOTHELIAL
PROLIFERATION, NO TUMOR SEEN PER [REDACTED]

Gross Description: Received for frozen section labeled, ,
, diaphragmatic adhesion". It consists of a soft tan pink
irregular tissue fragment measuring 2 x 2 x 0.5 cm. Entirely frozen in
4FS.

Source of Tissue: 5. Labeled #5, "11L lymph node"

Gross Description: Received fresh labeled, ,
level 11 lymph node". It consists of multiple soft black brown anthracotic
lymph nodes measuring from 0.2 up to 0.7 cm in greatest dimension. The
lymph node are entirely submitted in 5A-5B.

Source of Tissue: 6. Labeled #6, "12L lymph node"

[page 3 of 4]
Gross Description: Received fresh labeled, ", level 12 lymph node". It consists of two soft black brown anthracotic lymph nodes measuring from 0.8 up to 1.1 cm in greatest dimension. Each lymph node is bisected and entirely submitted in 6A.

Source of Tissue: 7. Labeled #7, "level 8 lymph node"

Gross Description: : Received fresh labeled, ", level 8 lymph node". It consists of two soft black brown anthracotic lymph nodes measuring from 0.5 up to 0.7 cm in greatest dimension. Entirely submitted in 7A.

Source of Tissue: 8. Labeled #8, level 7 lymph node"

Gross Description: : Received fresh labeled, , level 7 lymph node". It consists of multiple brown anthracotic lymph nodes measuring from 0.2 up to 2 cm in greatest dimension. The largest lymph node is bisected and the specimen is entirely submitted in 8A-8B.

Designation of Sections: 8A- largest lymph node bisected, 8B- three additional smaller lymph nodes

Source of Tissue: 9. Labeled #9, "left lung"

Intraoperative Consultation: NEGATIVE BRONCHIAL MARGIN PER J

Gross Description: Received fresh labeled, ", left lung". It consists of a complete left pneumonectomy specimen weighing a total of 753 grams with an overall measurement of 29 x 18.5 x 8 cm in greatest dimension. The upper lobe measures 18.5 x 12.5 x 5 cm in greatest dimension. The upper lobe is serially sectioned to reveal a homogenous, spongy, pale cut surface. The lower lobe measures 19.5 x 12.5 x 8.5 cm in greatest dimension. The lower lobe is serially sectioned to show an 8.5 x 7.5 x 6 cm ill defined firm brown tumor mass that comes within 5 cm of the closest bronchial and vascular margins. The mass comes within 0.1 cm of the pleura. The bronchial and vascular margins are grossly unremarkable. Multiple scattered black brown anthracotic peribronchial lymph nodes are identified measuring from 0.1 up to 1.2 cm in greatest dimension. The bronchial margin is entirely frozen in 9FS. Random sections of the remainder of specimen are submitted in 9A-9L.

Designation of Sections: 9FS- frozen section, 9A- vascular margin, 9B- additional random section of bronchus, 9C-9E- random section of tumor of the closest pleura, 9F- tumor by adjacent uninvolved parenchyma, 9G- uninvolved lower lobe, 9H-9I- upper lobe, 9J-9L- peribronchial lymph node

Source of Tissue: 10. Labeled #10, "new bronchial margin"

Gross Description: Received fresh labeled, ", new bronchial margin". It consists of a soft tan pink irregular tissue fragment measuring 1.2 cm in length and 1.7 cm in diameter. The specimen

[page 4 of 4]
is bisected and entirely submitted in 10A-10B.

TCGA-64-5779

Designation of Sections: 10A- proximal end, 10B- distal end

Source of Tissue: 11. Labeled #11, "level 6 lymph node"

Gross Description: Received fresh labeled, ,
level 6 lymph node. It consists of multiple soft yellow tan irregular
tissue fragments measuring 1.7 x 1.5 x 0.5 cm. Entirely submitted in 11A.

LUNG TEMPLATE

Specimen Type
Pneumectomy

Laterality
Left

Tumor Site
Lower lobe

Tumor Size
Greatest dimension: 8.5 cm

Histologic Type
Invasive adenocarcinoma with
Acinar morphology(ies)

Histologic Grade
Poorly differentiated

Extension of Tumor
Carcinoma does not involve visceral pleura

Venous (Large Vessel) Invasion
Absent

Arterial (Large Vessel) Invasion
Absent

Margins
Margins uninvolved by invasive carcinoma
Distance from closest margin 5.0 cm

Regional Lymph Nodes
53 regional lymph nodes examined
Regional lymph node metastasis
4 ipsilateral peribronchial and/or hilar lymph node(s) with
metastatic carcinoma (N1)
7 ipsilateral mediastinal and/or subcarinal lymph node(s) with metastatic
carcinoma (N2)
pTNM: T2 N2 Mx

Source: NCI Genomic Data Commons file 08d673e1-e9d4-4ab5-91d8-76617fd13a13 (TCGA-64-5779.74ED3C2E-6708-48D7-BC21-5FC04999614F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).